Gene-level copy-number profile of tumor specimen ALCH-B1XR-TTP1-A from ALCHEMIST case ALCH-B1XR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.1 years (29,249 days).
Specimen ALCH-B1XR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7602e88d-23e3-44b8-bec9-e65935573c0e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,268 have no estimate.
https://portal.gdc.cancer.gov/files/97f3fb8b-52a2-4292-8ed7-b46b39101566

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 3,488; copy number 2: 46,165; copy number 3: 6,126; copy number 4: 37; copy number 5: 2,199; copy number 6: 253; copy number 7: 9; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:95,274,449–95,291,308, 1 gene: PROM2.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:76,609,986–76,627,261, 1 gene (within-gene range 0–4): POMZP3.
- chr10:116,590,385–116,645,143, 2 genes: PNLIPRP1, PNLIPRP2.
- chr15:25,182,385–25,225,284, 24 genes (within-gene range 0–2): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:64,701,248–64,775,589, 3 genes (within-gene range 0–2): AC100830.1, RBPMS2, MIR1272.
- chr15:64,841,883–64,868,002, 1 gene (within-gene range 0–2): PLEKHO2.
- chr15:85,744,109–85,794,925, 6 genes (within-gene range 0–2): AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–1): PKD1L2, RNU6-1191P, AC092718.9.
- chr16:89,873,570–89,920,973, 3 genes (within-gene range 0–1): TCF25, AC092143.3, MC1R.
- chr16:89,948,697–90,002,161, 3 genes: DEF8, CENPBD1, AFG3L1P.
- chr17:44,290,856–44,291,151, 1 gene: RN7SL507P.
- chr19:24,004,358–24,163,425, 7 genes (within-gene range 0–2): RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:56,601,701–56,602,113, 1 gene: RPS4XP3.
- chr22:18,422,244–18,512,187, 3 genes: FAM230A, AC023490.2, FAM247B.
- chr22:18,527,157–18,530,573, 2 genes: AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,466 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,227,264–241,354,027, 4 genes, copy number 5–7: HDLBP, SEPTIN2, AC104841.1, AC005104.1.
- chr5:58,198–52,959,209, 712 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:151,212,150–154,420,984, 37 genes, copy number 5 (within-gene range 1–5): GM2A, SLC36A3, SLC36A2, ATP6V1G1P5, AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.1, SPARC, CLMAT3, RN7SKP232, AC011374.2, ATOX1, AC091982.1, RPLP1P6, AC091982.3, G3BP1, GLRA1, AC091982.2, RNA5SP198, LINC01933, AC008571.2, NMUR2, AC008571.1, LINC01470, GRIA1, RN7SL177P, LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10.
- chr5:154,337,471–154,349,725, 4 genes, copy number 5 (within-gene range 2–5): HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P.
- chr6:167,795,530–167,825,145, 2 genes, copy number 5 (within-gene range 2–5): AL009178.2, AL009178.3.
- chr7:76,521,611–76,541,459, 4 genes, copy number 9: AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr8:34,174,886–145,066,685, 1,691 genes, copy number 5–6 (broad region; genes not listed).
- chr19:1,086,574–1,095,380, 1 gene, copy number 5 (within-gene range 3–5): POLR2E.
- chr22:18,533,646–18,638,405, 7 genes, copy number 6–7: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2.
- chr22:18,733,914–18,757,906, 1 gene, copy number 9: FAM230E.
- chr22:18,846,811–18,894,407, 3 genes, copy number 5–6 (within-gene range 2–6): AC008132.1, BCRP7, FAM230F.

Autosomal genes at a single copy (total copy number 1): 3,488. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
